Somatic mutation profile of tumor specimen TCGA-E6-A1LX-01A (aliquot TCGA-E6-A1LX-01A-11D-A14G-09) from TCGA case TCGA-E6-A1LX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 40.3 years (14,731 days).
Specimen TCGA-E6-A1LX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a729d200-1276-4368-aa18-70c929f946fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E6-A1LX-10A (Blood Derived Normal), aliquot TCGA-E6-A1LX-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8a0b9c3-5979-4dd6-8478-118440097709

The open-access MAF lists 13,922 somatic variants for this specimen: 10,823 protein-altering or splice-affecting, 2,773 silent, 326 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9,335, Silent 2,773, Nonsense Mutation 1,145, Splice Site 183, Intron 152, Splice Region 78, RNA 75, 3'UTR 39, Frame Shift Ins 33, Frame Shift Del 31, 5'Flank 28, 3'Flank 16.

Variants (750 of 13,922; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs387907208, CM124860, COSV53963892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs199422227, CM920368, COSV61712686; ClinVar: pathogenic; called by mutect2, varscan2
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, varscan2
- ASPA | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs937670540, CM960089; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.6232C>T p.R2078* | Nonsense Mutation (SNP) | VAF 40/96 reads (42%) | catalogued as rs199422168, CM095684, COSV54125033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP7B | c.2383C>T p.L795F | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751710854, CM970141; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- BCL6 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 14/84 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV51649761; called by muse, mutect2, varscan2
- C8orf37 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907136, CM120200, COSV99713098; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CC2D2A | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs896947430, COSV67502337; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.5030G>A p.R1677Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886308, CM010201, CM113173, CM970369, COSV60366574; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DPT | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748718975; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSG1 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as rs397515639, CM010214; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EFHC1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs796052414, COSV100932128; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EOGT | c.1130G>A p.R377Q (on ENST00000383701 / NM_001278689.2; = p.R293Q on NM_173654.3) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776995, CM132505, COSV55153518; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERCC6 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs767247987, CM099974, COSV63387759; ClinVar: likely pathogenic; called by mutect2, varscan2
- FBN2 | c.3430G>A p.E1144K | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs200060005, CM1412995, COSV52489870, COSV52518440; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FLG | c.779C>A p.S260* | Nonsense Mutation (SNP) | VAF 23/131 reads (18%) | catalogued as rs199885226; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAN | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as rs119485090, CM020938, COSV101633963; ClinVar: pathogenic; called by mutect2, varscan2
- GJA5 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs387906613, CM104883, COSV99605540; ClinVar: pathogenic; called by mutect2, varscan2
- IFT81 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs546724699; ClinVar: pathogenic; called by mutect2, varscan2
- KCNB1 | c.1248C>A p.F416L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1569017015, CM160308; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRIT1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as rs886039402, CM022620, COSV60667006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LEMD3 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as rs749951964, CM061095, COSV57653886; ClinVar: pathogenic; called by muse, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MOCS1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893969, CM981300, COSV57933999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 24/69 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs397516127, CM031273, CM973126, COSV62516387; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- MYO3A | c.2636-1G>T p.X879_splice | Splice Site (SNP) | VAF 10/70 reads (14%) | catalogued as rs1564602202, COSV56335488; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYPN | c.3169C>T p.R1057* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs1057519572, COSV100590724; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- NAGLU | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.645); catalogued as rs1183634153, CM990922, COSV56796168; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as rs797045752, COSV56953286; ClinVar: pathogenic; called by muse, mutect2
- NSD1 | c.6049C>T p.R2017W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587784176, CM031305, COSV100728999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OTC | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as rs66521141, CM001741, CM001742, COSV99234242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAH | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); catalogued as rs62644465, CD159609, CM971136; ClinVar: not provided / likely pathogenic; called by mutect2, varscan2
- PAX6 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as rs1131692296, CP984557, COSV53793322; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH19 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064794763, COSV55261875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PEX1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as rs201415996, COSV50395532; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1133G>A p.C378Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.86); PolyPhen benign (0.402); catalogued as rs397514565, CM126691, COSV55930877, COSV55952006; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- POMGNT1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 19/101 reads (19%) | PolyPhen probably damaging (0.998); catalogued as rs193919336, CM042138; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | hotspot (GDC flag); catalogued as rs759850701, COSV59954557; called by muse, mutect2, varscan2
- PTEN | c.104T>C p.M35T | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs121909225, CM014083, CM981665, COSV100911372, COSV64292490; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTEN | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1111457, COSV64291669, COSV64295080, COSV64295612; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RICTOR | c.3302C>T p.S1101L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs776074870, COSV57119127; called by muse, mutect2, varscan2
- RPS6KA3 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs122454127, CM992428, COSV65387529; ClinVar: pathogenic; called by muse, varscan2
- RSPO2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758888137, COSV52641662; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.416G>A p.R139Q (on ENST00000344691 / NM_001001890.3; = p.R166Q on NM_001754.5) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1060499616, CM992139, COSV55866502, COSV55867644, COSV55875824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SBF2 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 20/105 reads (19%) | catalogued as rs120074139, CM042330; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.4547C>T p.S1516L (on ENST00000303395 / NM_001202435.3; = p.S1505L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs139300715, CM024310, CM1511239, COSV57665028; ClinVar: uncertain significance / likely benign / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.5830C>T p.R1944* (on ENST00000333535 / NM_198056.3; = p.R1943* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs794728940, CM143806, COSV61142776; ClinVar: likely pathogenic / uncertain significance / not provided / pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as rs1480085793, CM093256; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SETBP1 | c.2602G>A p.D868N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267607042, CM103046, COSV56311800, COSV56326819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SI | c.5110C>T p.R1704* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs779803851, COSV100015478, COSV52275176; ClinVar: pathogenic / uncertain significance; called by muse, varscan2
- SLC22A5 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185551386, CM104586, COSV55372082; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC37A4 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121908978, CM023375; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STAT3 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs113994137, CM077976, COSV52885689; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 29/151 reads (19%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TBC1D24 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs483352866, CM146963, COSV99564594; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TLK2 | c.2155C>T p.R719* (on ENST00000326270 / NM_001284333.2; = p.R697* on NM_006852.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as rs1568027692, COSV58306512; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by mutect2, varscan2
- TTN | c.53272C>T p.R17758* (on ENST00000591111; = p.R10334* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as rs768073446, COSV100635497; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- UPF3B | c.1288C>T p.R430* (on ENST00000276201 / NM_080632.3; = p.R417* on NM_023010.3) | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as rs122468181, CM074621, COSV52229788; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VSX2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912543, CM001965, CM001966, COSV56218559; ClinVar: pathogenic; called by mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1555C>A p.L519M (on ENST00000373993 / NM_138932.2; = p.L511M on NM_014576.4) | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs546119810; called by mutect2, varscan2
- A2M | c.3890G>A p.R1297H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs755149170, COSV59389635; called by muse, mutect2, varscan2
- A2M | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs377622666; called by muse, mutect2, varscan2
- A4GNT | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV52628536; called by muse, varscan2
- AADACL4 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.035); catalogued as rs1399332564; called by muse, varscan2
- AAK1 | c.2402C>A p.S801Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1458630473, COSV68642719; called by muse, mutect2, varscan2
- AARS1 | c.2083C>T p.R695* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs761043713, COSV99933718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as COSV99771380; called by muse, mutect2, varscan2
- AASDH | c.1583T>C p.I528T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs1314941974; called by muse, mutect2, varscan2
- AATF | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs760234359; called by muse, mutect2, varscan2
- ABCA10 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs546114873, COSV99288134; called by mutect2, varscan2
- ABCA12 | c.6100A>T p.N2034Y (on ENST00000272895 / NM_173076.3; = p.N1716Y on NM_015657.3) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55948348; called by muse, mutect2, varscan2
- ABCA12 | c.5600G>T p.R1867I (on ENST00000272895 / NM_173076.3; = p.R1549I on NM_015657.3) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV55967642; called by muse, mutect2, varscan2
- ABCA12 | c.2851G>A p.E951K (on ENST00000272895 / NM_173076.3; = p.E633K on NM_015657.3) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1353723813, COSV55948964; called by muse, mutect2, varscan2
- ABCA13 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752688275; called by mutect2, varscan2
- ABCA13 | c.2638G>T p.D880Y | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs747178673, COSV101330013; called by mutect2, varscan2
- ABCA13 | c.6784G>T p.D2262Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV70032492; called by muse, varscan2
- ABCA13 | c.6793G>A p.E2265K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV101330198; called by muse, varscan2
- ABCA13 | c.8967G>T p.K2989N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as COSV71285627; called by muse, mutect2, varscan2
- ABCA13 | c.13609G>A p.A4537T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs780658231; called by muse, mutect2, varscan2
- ABCA13 | c.14118G>T p.K4706N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV68948915; called by mutect2, varscan2
- ABCA13 | c.14588G>T p.R4863L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68944727, COSV68948204; called by muse, mutect2
- ABCA13 | c.14862A>C p.K4954N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV68948236; called by muse, mutect2, varscan2
- ABCA3 | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867072001; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV57054263; called by muse, mutect2, varscan2
- ABCA5 | c.3403G>T p.E1135* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV67015692; called by muse, mutect2, varscan2
- ABCA5 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101201254; called by muse, mutect2, varscan2
- ABCA6 | c.2987G>A p.R996Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs138416476, COSV52637314; called by muse, mutect2, varscan2
- ABCA6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374410367; called by mutect2, varscan2
- ABCA9 | c.96+1G>A p.X32_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100383710; called by muse, mutect2, varscan2
- ABCB1 | c.3298G>T p.E1100* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV55967003, COSV99713627; called by muse, mutect2, varscan2
- ABCB1 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV55950310; called by muse, mutect2, varscan2
- ABCB11 | c.3826C>T p.R1276C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755385304; called by muse, varscan2
- ABCB4 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs370195624, CM159632; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, varscan2
- ABCB5 | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as COSV51717016; called by muse, mutect2, varscan2
- ABCC1 | c.4075G>A p.A1359T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs779040246; called by muse, mutect2, varscan2
- ABCC10 | c.3455A>G p.D1152G (on ENST00000372530 / NM_001198934.2; = p.D1124G on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.824); catalogued as rs1178459303; called by muse, mutect2, varscan2
- ABCC8 | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.692); catalogued as rs1225850029, CM1411306, COSV56852110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs761160857, COSV56859074; called by muse, mutect2, varscan2
- ABCC9 | c.4156C>T p.R1386C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751670196; called by muse, mutect2, varscan2
- ABCC9 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99686305; called by muse, mutect2
- ABCD3 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV100239090; called by muse, mutect2, varscan2
- ABCD3 | c.633T>G p.F211L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1355916893; called by muse, mutect2, varscan2
- ABCD3 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV64642479; called by muse, mutect2, varscan2
- ABCE1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV56846807; called by muse, mutect2, varscan2
- ABCF3 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770951242, COSV53051574; called by mutect2, varscan2
- ABHD13 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV65535610; called by muse, mutect2, varscan2
- ABHD14B | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV56473800; called by muse, mutect2, varscan2
- ABHD4 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as rs763873898, COSV53530568; called by mutect2, varscan2
- ABHD8 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99917255; called by muse, mutect2, varscan2
- ABI3BP | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460896535; called by muse, mutect2, varscan2
- ABI3BP | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777320308, COSV52541461; called by muse, varscan2
- ABI3BP | c.141C>A p.F47L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52529920; called by muse, varscan2
- ABLIM1 | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs771839558; called by muse, mutect2, varscan2
- ABTB2 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs371505033; called by mutect2, varscan2
- AC006059.2 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100046044; called by mutect2, varscan2
- AC011448.1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as rs752678686, COSV52277658; called by muse, mutect2, varscan2
- AC023055.1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs751145396; called by mutect2, varscan2
- AC098582.1 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV52022607; called by muse, mutect2, varscan2
- AC104389.6 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as CM055286; called by muse, mutect2, varscan2
- AC231657.3 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); catalogued as COSV100540161; called by muse, mutect2, varscan2
- ACAD9 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1304343334; called by muse, mutect2, varscan2
- ACAD9 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs745926616, COSV58306557; called by muse, mutect2, varscan2
- ACAD9 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs368227855; called by muse, mutect2, varscan2
- ACAN | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs887656896, COSV61361610; called by muse, mutect2, varscan2
- ACBD3 | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766741908, COSV64729849; called by muse, mutect2, varscan2
- ACBD5 | c.1204G>A p.E402K (on ENST00000375888 / NM_001352568.1; = p.E393K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.167); catalogued as rs777230785, COSV65519169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACBD5 | c.657G>T p.K219N (on ENST00000375888 / NM_001352568.1; = p.K210N on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV65520673; called by muse, mutect2, varscan2
- ACE2 | c.2302C>T p.R768W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs140016715, COSV53024501; called by mutect2, varscan2
- ACER1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.703); catalogued as rs371084829; called by muse, mutect2, varscan2
- ACER2 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1272815814; called by muse, varscan2
- ACKR2 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs1488885862, COSV56180110; called by muse, mutect2, varscan2
- ACLY | c.2974G>T p.D992Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59862038; called by muse, mutect2, varscan2
- ACLY | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.154); catalogued as rs782226163, COSV104418799; called by muse, mutect2, varscan2
- ACOT11 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs764870998; called by muse, mutect2, varscan2
- ACOT12 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs147623252, COSV100296919; called by muse, mutect2, varscan2
- ACOT6 | c.357C>A p.F119L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV66969232; called by muse, mutect2, varscan2
- ACOX3 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs762558027, COSV62711619; called by muse, mutect2, varscan2
- ACSBG2 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs767667346, COSV53127616; called by muse, mutect2, varscan2
- ACSL1 | c.2027C>T p.A676V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs759188602, COSV55660753; called by muse, mutect2, varscan2
- ACSL1 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as rs1361601006, COSV55660967; called by muse, mutect2, varscan2
- ACSL3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs531866665, COSV62482434; called by muse, mutect2, varscan2
- ACSL4 | c.1139G>T p.R380I (on ENST00000340800 / NM_022977.2; = p.R339I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100538330; called by muse, mutect2, varscan2
- ACSL4 | c.331A>C p.N111H (on ENST00000340800 / NM_022977.2; = p.N70H on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61614282; called by muse, mutect2, varscan2
- ACSL4 | c.196G>A p.D66N (on ENST00000340800 / NM_022977.2; = p.D25N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs1363259105, COSV61613928; called by muse, mutect2, varscan2
- ACTL8 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs115824043, COSV64861249; called by muse, mutect2, varscan2
- ACTL9 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs372054892, COSV61005858; called by muse, mutect2, varscan2
- ACTN4 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs1178103660; called by muse, mutect2
- ACTR5 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377739375; called by muse, varscan2
- ACTR5 | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV54759677; called by muse, varscan2
- ACTR6 | c.805C>T p.R269C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751590872, COSV51843879; called by mutect2, varscan2
- ACVR1C | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267033436, COSV54648518; called by muse, mutect2, varscan2
- ACVR2B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as rs371756878, COSV61702820; called by muse, mutect2, varscan2
- ACVR2B | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61701785; called by muse, mutect2, varscan2
- ADAD1 | c.1352G>T p.R451I | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56646939; called by muse, mutect2, varscan2
- ADAM12 | c.2602C>T p.R868W | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1294826675; called by muse, varscan2
- ADAM12 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200391541; called by muse, mutect2, varscan2
- ADAM17 | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs530963981, COSV60398150; called by muse, mutect2, varscan2
- ADAM19 | c.1593C>T p.P531= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as rs142646672; called by mutect2, varscan2
- ADAM19 | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as rs1250579607; called by muse, mutect2, varscan2
- ADAM20 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.392); catalogued as rs754605627; called by muse, mutect2, varscan2
- ADAM21 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs144574931; called by mutect2, varscan2
- ADAM21 | c.1808A>G p.D603G | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761304781; called by muse, mutect2, varscan2
- ADAM30 | c.1865A>T p.N622I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1047372526; called by muse, mutect2, varscan2
- ADAMDEC1 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753833406, COSV56474653, COSV99835826; called by muse, mutect2, varscan2
- ADAMDEC1 | c.763-1G>T p.X255_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV56477488; called by muse, mutect2, varscan2
- ADAMDEC1 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as rs1351755384, COSV99835912; called by muse, mutect2, varscan2
- ADAMTS10 | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV54351845; called by muse, mutect2
- ADAMTS14 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1203416117; called by muse, mutect2, varscan2
- ADAMTS16 | c.759G>T p.K253N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs750965156; called by mutect2, varscan2
- ADAMTS16 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1431159881, COSV57010074; called by muse, mutect2, varscan2
- ADAMTS17 | c.2197G>T p.E733* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV51491654; called by muse, varscan2
- ADAMTS19 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs188910013, COSV50731320; called by mutect2, varscan2
- ADAMTS20 | c.3427G>A p.A1143T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745904616; called by mutect2, varscan2
- ADAMTS3 | c.2648G>A p.R883H | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1419506592, COSV54388702, COSV54392491; called by muse, varscan2
- ADAMTS5 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.71); catalogued as rs748491619, COSV53177561; called by mutect2, varscan2
- ADAMTS5 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs961002612; called by muse, mutect2, varscan2
- ADAMTSL1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs200648653, COSV99442517; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1466985456; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); catalogued as rs370505336; called by muse, mutect2, varscan2
- ADCK5 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as rs782398356; called by muse, mutect2, varscan2
- ADCY3 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1285631837, COSV53168828; called by muse, mutect2, varscan2
- ADCY3 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53167596; called by muse, mutect2
- ADCY4 | c.1988G>T p.R663I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV100156423; called by muse, mutect2, varscan2
- ADD1 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370911124; called by muse, mutect2, varscan2
- ADD2 | c.1786T>C p.S596P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs529439868; called by muse, mutect2, varscan2
- ADD2 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52466514; called by muse, mutect2
- ADGRA1 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs749746034, COSV66927846; called by muse, mutect2, varscan2
- ADGRA2 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.292); catalogued as rs565289543, COSV59442688; called by mutect2, varscan2
- ADGRA3 | c.2810G>A p.S937N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1321122468, COSV51566774; called by muse, mutect2, varscan2
- ADGRB2 | c.3514G>A p.V1172I | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs368713364; called by muse, mutect2, varscan2
- ADGRB3 | c.1833C>A p.F611L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.437); catalogued as COSV65383768; called by muse, mutect2, varscan2
- ADGRD1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs139478688; called by muse, mutect2, varscan2
- ADGRD1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as rs775109187, COSV55440626; called by muse, mutect2
- ADGRF4 | c.1065G>T p.K355N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.08); catalogued as COSV51954952; called by muse, mutect2, varscan2
- ADGRF4 | c.2083G>T p.G695* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51957083; called by muse, mutect2, varscan2
- ADGRF5 | c.3129G>T p.K1043N | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.52); catalogued as rs1376923140, COSV51932505, COSV51935195; called by muse, mutect2, varscan2
- ADGRF5 | c.1117T>G p.L373V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99345573; called by muse, mutect2, varscan2
- ADGRG3 | c.256A>C p.K86Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1315502886; called by muse, mutect2
- ADGRG4 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs745479559, COSV54957864; called by muse, mutect2, varscan2
- ADGRG4 | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54960919; called by muse, mutect2, varscan2
- ADGRG4 | c.7467G>T p.E2489D | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs747772436; called by muse, mutect2, varscan2
- ADGRG4 | c.7887C>A p.F2629L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1334865153, COSV99794222; called by mutect2, varscan2
- ADGRG6 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1317407930; called by muse, varscan2
- ADGRG6 | c.2041C>T p.L681F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99746705; called by muse, mutect2
- ADGRL1 | c.1975G>A p.A659T (on ENST00000340736 / NM_001008701.3; = p.A654T on NM_014921.5) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs931391613; called by muse, mutect2, varscan2
- ADGRL2 | c.1029T>G p.I343M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs552007701, COSV54670069; called by mutect2, varscan2
- ADGRL2 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs767811966, COSV54675510; called by mutect2, varscan2
- ADGRL2 | c.2849A>C p.K950T (on ENST00000370717 / NM_001366005.1; = p.K937T on NM_012302.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs758484253; called by muse, mutect2, varscan2
- ADGRL3 | c.3619C>T p.R1207* (on ENST00000506720 / NM_001322402.2; = p.R1139* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | catalogued as COSV72230574; called by muse, mutect2, varscan2
- ADGRL4 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs191635062; called by muse, mutect2, varscan2
- ADGRV1 | c.4657C>T p.R1553C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1435003118, COSV101315709; called by muse, mutect2, varscan2
- ADGRV1 | c.9680G>A p.R3227Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs371542701, COSV101316731; ClinVar: uncertain significance; called by mutect2, varscan2
- ADGRV1 | c.11059C>T p.R3687C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1010063079; called by muse, mutect2, varscan2
- ADGRV1 | c.13049C>A p.S4350Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.172); catalogued as COSV67984745; called by muse, mutect2
- ADGRV1 | c.14605C>A p.L4869I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV101315430; called by muse, mutect2, varscan2
- ADH1B | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs187446108, COSV104396458; called by mutect2, varscan2
- ADH1C | c.689T>G p.F230C | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72463671; called by muse, mutect2, varscan2
- ADH5 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as rs761349329, COSV56447491; called by muse, mutect2, varscan2
- ADH6 | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV52955169; called by muse, mutect2, varscan2
- ADHFE1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as rs562550101; called by muse, mutect2, varscan2
- ADIPOR2 | c.35G>T p.S12I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV63945747; called by muse, mutect2, varscan2
- ADORA2A | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748699595, COSV58378823; called by mutect2, varscan2
- ADPRM | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.043); catalogued as COSV101126044; called by muse, mutect2, varscan2
- ADRA2B | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs1278462619, COSV69787669; called by mutect2, varscan2
- AFAP1L1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV57047264; called by muse, mutect2, varscan2
- AFDN | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs747022102, COSV60050468; called by muse, mutect2, varscan2
- AFDN | c.3832G>T p.E1278* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV60042935; called by muse, mutect2, varscan2
- AFF1 | c.3251C>A p.S1084Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV57116952; called by mutect2, varscan2
- AFF2 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as rs782175109, COSV60654671; called by muse, mutect2, varscan2
- AFF2 | c.3270C>T p.F1090= | Splice Region (SNP) | VAF 16/40 reads (40%) | catalogued as rs371376716, COSV99059882; ClinVar: uncertain significance; called by muse, varscan2
- AFF4 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.968); catalogued as rs1163232552, COSV54792878; called by muse, mutect2, varscan2
- AFM | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV99888906; called by muse, mutect2, varscan2
- AGBL1 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV66871290; called by muse, mutect2, varscan2
- AGBL1 | c.2886G>T p.E962D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66865227, COSV66869636; called by muse, mutect2, varscan2
- AGBL5 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV59935469; called by mutect2, varscan2
- AGGF1 | c.2038A>C p.K680Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1416005226, COSV100461858; called by muse, mutect2
- AGMO | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs768857037; called by muse, mutect2, varscan2
- AGTPBP1 | c.2729G>A p.R910H (on ENST00000357081 / NM_001330701.2; = p.R870H on NM_015239.2) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61270790; called by muse, mutect2, varscan2
- AGTPBP1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.291); catalogued as rs1433230227, COSV61274122; called by muse, mutect2, varscan2
- AGXT | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56754454; called by muse, mutect2, varscan2
- AGXT2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs1289298122, COSV51487805; called by muse, mutect2, varscan2
- AGXT2 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51483920; called by muse, mutect2, varscan2
- AHCTF1 | c.3938C>A p.S1313Y (on ENST00000366508; = p.S1287Y on NM_015446.5) | Missense Mutation (SNP) | VAF 90/118 reads (76%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV58252902; called by muse, mutect2, varscan2
- AHCYL2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); catalogued as rs1022825206; called by muse, mutect2, varscan2
- AHNAK | c.14092G>A p.E4698K | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs574303217; called by muse, mutect2, varscan2
- AHNAK | c.7834G>A p.E2612K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.485); catalogued as rs2868812, COSV57222460; called by muse, mutect2, varscan2
- AHNAK2 | c.14090C>T p.S4697L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.415); catalogued as rs377637525; called by muse, mutect2, varscan2
- AHNAK2 | c.8923G>T p.D2975Y | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV60918229; called by muse, mutect2, varscan2
- AHNAK2 | c.7937G>A p.S2646N | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as rs757902355; called by mutect2, varscan2
- AIF1 | c.220C>A p.L74M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.17); catalogued as COSV61962540; called by muse, mutect2, varscan2
- AIFM1 | c.861T>C p.I287= | Splice Region (SNP) | VAF 11/38 reads (29%) | catalogued as COSV54852585; called by muse, mutect2, varscan2
- AIMP1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs1325753902; called by mutect2, varscan2
- AK5 | c.1004C>T p.S335L (on ENST00000354567 / NM_174858.3; = p.S309L on NM_012093.4) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs145823239; called by mutect2, varscan2
- AK9 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374987709; called by mutect2, varscan2
- AKAP13 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs114690403; called by muse, mutect2, varscan2
- AKAP13 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.143); catalogued as rs754487409, COSV100774323; called by mutect2, varscan2
- AKAP13 | c.2327A>G p.D776G | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs907574953; called by muse, mutect2, varscan2
- AKAP4 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62074972; called by muse, mutect2, varscan2
- AKAP9 | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV62348968; called by muse, varscan2
- AKR1A1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148412869; called by muse, mutect2, varscan2
- AKR1C3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs782018434; called by muse, mutect2, varscan2
- AKR1C4 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs782235828, COSV54122178, COSV54124219; called by muse, mutect2, varscan2
- AKR1C4 | c.928T>C p.F310L | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV54124319; called by muse, mutect2, varscan2
- AKR1E2 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs773986145; called by muse, mutect2, varscan2
- AKT1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs755597789, COSV62572701; called by mutect2, varscan2
- AKT1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs764863282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKT3 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV55606314; called by muse, mutect2, varscan2
- AKT3 | c.856A>C p.K286Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55616449; called by muse, mutect2, varscan2
- AKT3 | c.453G>T p.L151F | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99795304, COSV99796447; called by muse, mutect2, varscan2
- AL592490.1 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1033970606; called by muse, varscan2
- AL645922.1 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.227); catalogued as rs1291146038, COSV54962581; called by muse, mutect2, varscan2
- ALAS1 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV59629095; called by muse, mutect2, varscan2
- ALAS2 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV58187898; called by muse, mutect2, varscan2
- ALB | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs1485868409, COSV55737756; called by muse, mutect2, varscan2
- ALB | c.737G>T p.R246I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as CM147063; called by mutect2, varscan2
- ALB | c.1194C>T p.F398= | Splice Region (SNP) | VAF 12/42 reads (29%) | catalogued as rs770952660, COSV55735522, COSV55737469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1A3 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs141839784; called by muse, mutect2, varscan2
- ALDH1A3 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs747991447, COSV60901344; called by muse, mutect2, varscan2
- ALDH3A1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.577); catalogued as rs750383473, COSV56736817; called by muse, mutect2, varscan2
- ALDH4A1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99311974; called by muse, varscan2
- ALDH5A1 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377658514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG13 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52640444; called by muse, varscan2
- ALG13 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV52644769; called by muse, varscan2
- ALG14 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs200774756; called by mutect2, varscan2
- ALG6 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV54763161; called by muse, varscan2
- ALK | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs368581969, COSV66579077; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALMS1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV52515737; called by muse, mutect2, varscan2
- ALOX12 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs752227569; called by mutect2, varscan2
- ALOX12B | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59877146; called by mutect2, varscan2
- ALOX15 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs769786656; called by mutect2, varscan2
- ALOX15 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs776753182; called by mutect2, varscan2
- ALPG | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs749907696, COSV54968350; called by mutect2, varscan2
- ALPI | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.07); catalogued as rs761521664; called by muse, mutect2, varscan2
- ALPK2 | c.5894G>T p.R1965I | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64491955; called by muse, mutect2, varscan2
- ALPK2 | c.2561C>A p.S854Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as COSV64491420; called by mutect2, varscan2
- ALS2CL | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs774260937; called by muse, mutect2, varscan2
- AMBN | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59827212; called by muse, mutect2, varscan2
- AMBRA1 | c.2837C>T p.S946L (on ENST00000458649 / NM_001367468.1; = p.S856L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs932975059, COSV54062015; called by muse, mutect2, varscan2
- AMD1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs753517621, COSV64387769; called by muse, mutect2, varscan2
- AMDHD2 | c.135C>A p.F45L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1366305645; called by muse, mutect2, varscan2
- AMER1 | c.2700G>T p.E900D | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); catalogued as COSV57667461; called by muse, mutect2, varscan2
- AMIGO1 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.349); catalogued as rs1200989755, COSV63990410; called by muse, mutect2, varscan2
- AMPD1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs773353828, COSV100814865; called by mutect2, varscan2
- AMPH | c.2027A>G p.Y676C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100343278; called by muse, mutect2, varscan2
- ANAPC1 | c.4537G>A p.E1513K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV61979368; called by muse, mutect2, varscan2
- ANAPC1 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 28/150 reads (19%) | catalogued as COSV61976907; called by muse, varscan2
- ANGPT1 | c.572dup p.N191Kfs*7 | Frame Shift Ins (INS) | VAF 16/103 reads (16%) | catalogued as rs777650478, COSV104399203; called by mutect2, varscan2
- ANGPT2 | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV57335549; called by muse, mutect2, varscan2
- ANGPT4 | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs182043253; called by muse, mutect2, varscan2
- ANGPTL2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs199872129, COSV52219376; called by muse, mutect2, varscan2
- ANK1 | c.4958C>A p.S1653Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.013); catalogued as COSV55874964; called by mutect2, varscan2
- ANK1 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as CM032177, COSV55885886; called by muse, mutect2, varscan2
- ANK1 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV55874984, COSV55880954; called by muse, mutect2, varscan2
- ANK2 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs150488571; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- ANK2 | c.9587C>T p.S3196L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.254); catalogued as rs144719173, COSV52190287; called by mutect2, varscan2
- ANK2 | c.10175C>A p.S3392Y | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs769340917; called by mutect2, varscan2
- ANK2 | c.10925G>A p.R3642Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757939990, COSV52166643; called by muse, mutect2, varscan2
- ANK3 | c.12395C>A p.S4132Y (on ENST00000280772 / NM_001320874.2; = p.S653Y on NM_001149.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV55056815; called by muse, mutect2
- ANK3 | c.7858G>T p.E2620* | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as COSV55090262; called by muse, mutect2, varscan2
- ANK3 | c.4733C>A p.S1578Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99779435; called by muse, mutect2, varscan2
- ANK3 | c.3241C>T p.R1081* (on ENST00000280772 / NM_001320874.2; = p.R215* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs775324952, COSV55059130; called by muse, mutect2, varscan2
- ANK3 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs139879505; called by mutect2, varscan2
- ANKAR | c.3128G>T p.R1043I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs372369306, COSV55618459; called by muse, mutect2, varscan2
- ANKEF1 | c.1213T>C p.S405P | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1256039625; called by muse, varscan2
- ANKFY1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs766157391; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2980G>A p.D994N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.532); catalogued as rs1301002746, COSV99782569; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5516T>C p.V1839A | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); catalogued as rs1225136084, COSV104369727; called by muse, mutect2, varscan2
- ANKRD11 | c.5369C>T p.S1790L | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs761377016, COSV56366676; called by muse, mutect2, varscan2
- ANKRD11 | c.4177G>A p.E1393K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs757166671, COSV56372184; called by muse, varscan2
- ANKRD11 | c.2717G>A p.R906Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as rs763544660, COSV56376652; called by muse, varscan2
- ANKRD17 | c.4046G>A p.R1349H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1353324609, COSV58221646; called by muse, mutect2, varscan2
- ANKRD27 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs766519033, COSV60128664; called by mutect2, varscan2
- ANKRD30A | c.1802C>A p.S601Y (on ENST00000611781; = p.S545Y on NM_052997.2) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV64609660; called by muse, mutect2, varscan2
- ANKRD30A | c.4121T>G p.F1374C (on ENST00000611781; = p.F1318C on NM_052997.2) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV100654419; called by muse, mutect2, varscan2
- ANKRD34B | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV58613487; called by muse, mutect2, varscan2
- ANKRD34B | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV58614236, COSV58614678; called by muse, mutect2, varscan2
- ANKRD42 | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as rs568308910, COSV52618692; called by muse, mutect2, varscan2
- ANKRD49 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as rs767511021, COSV57060117; called by muse, mutect2, varscan2
- ANKRD50 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs1011161674, COSV72386347; called by mutect2, varscan2
- ANKRD6 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs926915572, COSV100330239; called by muse, mutect2, varscan2
- ANKRD7 | c.523A>C p.K175Q | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV54555091; called by muse, mutect2, varscan2
- ANKS1B | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs1314803484; called by muse, mutect2, varscan2
- ANKS1B | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61374040; called by muse, mutect2, varscan2
- ANLN | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs923512260, COSV56074093; called by muse, mutect2, varscan2
- ANO2 | c.1423G>T p.E475* (on ENST00000356134 / NM_001278597.3; = p.E479* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as rs761555644, COSV59022625; called by muse, mutect2, varscan2
- ANO2 | c.834G>A p.V278= (on ENST00000356134 / NM_001278597.3; = p.V282= on NM_001278596.3) | Splice Region (SNP) | VAF 15/73 reads (21%) | catalogued as COSV59045214; called by muse, mutect2, varscan2
- ANO3 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs754306957, COSV56785250, COSV56806565; called by muse, mutect2, varscan2
- ANO3 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1254525478, COSV56784546; called by muse, mutect2, varscan2
- ANO3 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV104375648; called by muse, mutect2, varscan2
- ANO3 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.889); catalogued as rs1458612996, COSV56788908; called by mutect2, varscan2
- ANO4 | c.337C>T p.R113* (on ENST00000392977 / NM_001286615.2; = p.R78* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs766790643, COSV54609036; called by muse, mutect2, varscan2
- ANO6 | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 26/116 reads (22%) | catalogued as rs751953918, COSV57668573; called by muse, mutect2, varscan2
- ANO6 | c.1611C>T p.F537= | Splice Region (SNP) | VAF 8/53 reads (15%) | catalogued as rs536008906, COSV57662793; called by mutect2, varscan2
- ANPEP | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs781733489; called by muse, mutect2, varscan2
- ANPEP | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as rs766949181, COSV100263556; called by muse, mutect2, varscan2
- ANTXR1 | c.667A>G p.I223V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.95); catalogued as rs920720283; called by muse, mutect2, varscan2
- ANTXR1 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); catalogued as rs766940480; called by muse, mutect2, varscan2
- ANTXR2 | c.1172G>T p.R391I | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56319488; called by muse, mutect2, varscan2
- ANXA10 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as rs374810057; called by muse, mutect2, varscan2
- ANXA5 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs141889791, COSV56638767; called by muse, varscan2
- ANXA9 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776885513, COSV56497500; called by muse, mutect2, varscan2
- AOAH | c.742T>G p.F248V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV51735399; called by mutect2, varscan2
- AOX1 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41309768, CM126499; called by mutect2, varscan2
- AP002748.5 | c.1819C>T p.R607* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as rs1434577015, CM1414734; called by muse, mutect2, varscan2
- AP1G2 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs747117877; called by mutect2, varscan2
- AP1G2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.856); catalogued as rs1169465240, COSV58116263; called by mutect2, varscan2
- AP3B1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as rs193920974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3B1 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs779980435, COSV99671089; called by mutect2, varscan2
- AP3B2 | c.2703C>A p.F901L (on ENST00000261722; = p.F895L on NM_004644.5) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.098); catalogued as rs1227277094, COSV104377777; called by muse, mutect2, varscan2
- AP3B2 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442353474, COSV55608425; called by muse, mutect2, varscan2
- AP3D1 | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769457714, COSV104416703; called by mutect2, varscan2
- AP4E1 | c.2532G>T p.K844N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV55916095, COSV55916170; called by muse, mutect2, varscan2
- AP5M1 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs925328183, COSV55105033; called by muse, mutect2, varscan2
- APAF1 | c.3286G>A p.D1096N (on ENST00000551964 / NM_181861.2; = p.D1042N on NM_001160.3) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs538479133; called by muse, mutect2, varscan2
- APBA2 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV67104459; called by muse, mutect2, varscan2
- APBA2 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV101258120, COSV101258206; called by mutect2, varscan2
- APBA2 | c.2028G>T p.Q676H | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV68794845; called by muse, mutect2, varscan2
- APBB1IP | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762052919, COSV100882264; called by mutect2, varscan2
- APBB2 | c.2158C>T p.R720* (on ENST00000295974 / NM_001166050.2; = p.R721* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as rs1560589921, COSV55948589; called by muse, mutect2, varscan2
- APC | c.6319G>A p.G2107S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57390454; called by muse, mutect2, varscan2
- APC | c.8021C>A p.S2674Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57331222, COSV99078819; called by muse, mutect2, varscan2
- APH1A | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.142); catalogued as rs368536742, COSV52530067; called by muse, varscan2
- APOA5 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs1245663934; called by muse, mutect2, varscan2
- APOA5 | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV57063080; called by mutect2, varscan2
- APOB | c.11279C>T p.S3760L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as rs779036508, COSV99265721; called by muse, varscan2
- APOB | c.9011C>A p.A3004D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV51923848; called by muse, mutect2, varscan2
- APOB | c.6634C>A p.L2212I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as CD1310131; called by muse, mutect2, varscan2
- APOBEC2 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.321); catalogued as rs1065197, COSV99775374; called by muse, mutect2, varscan2
- APOBR | c.2348C>T p.S783L (on ENST00000431282; = p.S792L on NM_018690.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs746161480, COSV60492290; called by muse, mutect2, varscan2
- APOH | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs55645281, COSV52771453; called by muse, mutect2
- APOL3 | c.1152G>T p.E384D (on ENST00000349314 / NM_145640.2; = p.E313D on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as COSV62579996; called by muse, mutect2, varscan2
- APOO | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.634); catalogued as rs868511129, COSV101004878; called by muse, mutect2, varscan2
- APPL1 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.885); catalogued as rs1281823497; called by muse, mutect2, varscan2
- AQP10 | c.165C>A p.F55L | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61474918; called by muse, mutect2, varscan2
- AQP9 | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs372374128; called by muse, mutect2, varscan2
- ARAP1 | c.1619G>A p.R540H (on ENST00000393609 / NM_001040118.2; = p.R295H on NM_015242.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs746910641, COSV61993762; called by mutect2, varscan2
- ARAP2 | c.4891C>T p.R1631W | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs747621294, COSV58289982; called by mutect2, varscan2
- ARAP3 | c.643G>T p.G215* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV53348300; called by muse, mutect2, varscan2
- ARGFX | c.221-1G>A p.X74_splice | Splice Site (SNP) | VAF 19/45 reads (42%) | catalogued as COSV57682087; called by muse, mutect2, varscan2
- ARHGAP10 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs765966630, COSV60608972; called by muse, mutect2, varscan2
- ARHGAP17 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757526992, COSV51509775; called by muse, mutect2, varscan2
- ARHGAP18 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as rs969461309, COSV63764944; called by muse, mutect2, varscan2
- ARHGAP20 | c.1450C>A p.L484I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99503255; called by muse, mutect2, varscan2
- ARHGAP25 | c.481C>T p.R161C (on ENST00000409202 / NM_001007231.3; = p.R153C on NM_014882.3) | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs141376321, COSV54900381; called by muse, mutect2, varscan2
- ARHGAP28 | c.1892C>T p.S631L (on ENST00000383472 / NM_001366230.1; = p.S472L on NM_001010000.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.313); catalogued as rs142301237; called by muse, mutect2, varscan2
- ARHGAP29 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1299495644, COSV53108702; called by muse, varscan2
- ARHGAP30 | c.3214G>T p.E1072* (on ENST00000368013 / NM_001025598.2; = p.E861* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV63515050; called by muse, mutect2, varscan2
- ARHGAP32 | c.3938G>T p.R1313I (on ENST00000310343 / NM_001378025.1; = p.R964I on NM_014715.4) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as COSV104403943; called by muse, mutect2, varscan2
- ARHGAP35 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs889033932; called by muse, mutect2, varscan2
- ARHGAP5 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766456413; called by muse, mutect2, varscan2
- ARHGEF10L | c.1736C>A p.A579D | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.169); catalogued as COSV51437310; called by muse, mutect2, varscan2
- ARHGEF10L | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs776331349, COSV51430988; called by muse, mutect2, varscan2
- ARHGEF11 | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV59353278; called by muse, mutect2, varscan2
- ARHGEF15 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs113540851; called by mutect2, varscan2
- ARHGEF16 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as rs559918389, COSV65681685; called by muse, mutect2, varscan2
- ARHGEF17 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as rs1285187269; called by muse, mutect2, varscan2
- ARHGEF2 | c.712G>A p.D238N (on ENST00000361247 / NM_001162383.2; = p.D210N on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761622296; called by muse, mutect2, varscan2
- ARHGEF25 | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs773245828, COSV99677993; called by muse, mutect2, varscan2
- ARHGEF26 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1236153082, COSV62845461, COSV62851083; called by muse, mutect2, varscan2
- ARHGEF26 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs903936492, COSV100726371, COSV62846065; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARHGEF40 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768330300, COSV53878795; called by muse, mutect2, varscan2
- ARHGEF40 | c.4097C>A p.S1366Y | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV53878152; called by muse, mutect2, varscan2
- ARID2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV104399055; called by mutect2, varscan2
- ARID2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs140086050, COSV57595654; called by muse, mutect2, varscan2
- ARIH1 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | catalogued as COSV65913399; called by muse, mutect2, varscan2
- ARL13A | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as rs199822800, COSV100879062; called by muse, mutect2, varscan2
- ARL13B | c.665G>A p.R222Q (on ENST00000394222 / NM_001174150.2; = p.R115Q on NM_144996.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1478163991, COSV100115133; called by muse, mutect2, varscan2
- ARL14 | c.30A>C p.Q10H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs1468058604; called by muse, mutect2, varscan2
- ARL14 | c.215G>T p.R72I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760666218; called by mutect2, varscan2
- ARMCX1 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.32); catalogued as COSV65705274; called by muse, mutect2, varscan2
- ARMCX5 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 14/115 reads (12%) | catalogued as COSV99863368; called by muse, varscan2
- ARMCX5-GPRASP2 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1267090365; called by muse, mutect2, varscan2
- ARMH4 | c.2219G>A p.R740H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750555182, COSV50767618; called by mutect2, varscan2
- ARMH4 | c.1900G>T p.D634Y | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50765288; called by muse, mutect2, varscan2
- ARMH4 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as rs200905995, COSV50764047; called by muse, mutect2, varscan2
- ARMT1 | c.44C>A p.S15* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV66179069; called by muse, varscan2
- ARNT | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV104416818; called by muse, mutect2, varscan2
- ARNTL2 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141432546; called by muse, mutect2, varscan2
- ARRDC1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.121); catalogued as rs1334788068; called by muse, mutect2, varscan2
- ARRDC4 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs753297131, COSV51419131; called by muse, mutect2, varscan2
- ARSB | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs758641798, COSV53718888; called by muse, varscan2
- ARSF | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1228335088; called by muse, mutect2, varscan2
- ARSF | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs751497726, COSV63838954; called by muse, mutect2, varscan2
- ARSG | c.40A>G p.S14G | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as COSV71593021; called by muse, mutect2, varscan2
- ASAP1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs960186277, COSV63044161; called by muse, varscan2
- ASB2 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs374433516; called by muse, mutect2, varscan2
- ASB5 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs534160855, COSV56671180; called by muse, varscan2
- ASCC3 | c.5860C>T p.R1954W | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs999281194, COSV64975834; called by muse, mutect2
- ASH1L | c.3904C>T p.R1302W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs746450493, COSV64210433; called by muse, mutect2, varscan2
- ASIC3 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.987); catalogued as rs778336098; called by muse, mutect2, varscan2
- ASIC4 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749947411; called by muse, mutect2, varscan2
- ASIC4 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559452870, COSV61733412; called by muse, mutect2, varscan2
- ASPH | c.1112A>C p.Y371S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs776684832; called by muse, mutect2, varscan2
- ASPM | c.8561G>T p.R2854I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs1398096432; called by muse, mutect2, varscan2
- ASPM | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs142655430, COSV54127984; called by mutect2, varscan2
- ASPM | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766198125, COSV54132241; called by muse, mutect2, varscan2
- ASPM | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs750028073, COSV54136796; called by muse, mutect2, varscan2
- ASPM | c.1949C>A p.S650Y | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54128271, COSV54128675; called by muse, mutect2, varscan2
- ASTE1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs773437504, COSV53909044; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ASTN2 | c.2945G>A p.R982H (on ENST00000313400 / NM_001365069.1; = p.R931H on NM_014010.5) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs139180322; called by mutect2, varscan2
- ASTN2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs758127962, COSV100523981, COSV100528998; called by mutect2, varscan2
- ASTN2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs777574038, COSV57811894; called by mutect2, varscan2
- ASTN2 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as rs374807129; called by mutect2, varscan2
- ASXL2 | c.4193C>T p.S1398L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.85); catalogued as rs190294224, COSV55458862; called by mutect2, varscan2
- ASXL2 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55453955, COSV55470068; called by muse, mutect2, varscan2
- ASXL3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1449951428; called by muse, mutect2, varscan2
- ASXL3 | c.449A>C p.Q150P | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52470547; called by muse, mutect2, varscan2
- ASXL3 | c.1711A>G p.K571E | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as COSV52457264; called by muse, mutect2, varscan2
- ASXL3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); catalogued as rs749484741, COSV52457610; called by mutect2, varscan2
- ATAD5 | c.3033G>T p.K1011N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1458417438, COSV58974463; called by muse, mutect2
- ATAT1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1404089307; called by muse, mutect2, varscan2
- ATF2 | c.1359G>T p.Q453H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV51369096; called by muse, mutect2, varscan2
- ATF6 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs146640460, COSV63408740; called by mutect2, varscan2
- ATF7IP | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as rs770191292, COSV53770969; called by muse, mutect2, varscan2
- ATF7IP2 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1361151528, COSV61092378, COSV61095454; called by muse, mutect2, varscan2
- ATG101 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1433822749; called by muse, mutect2, varscan2
- ATG14 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1361930940; called by muse, varscan2
- ATG16L1 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs774397068, COSV61465196; called by muse, mutect2, varscan2
- ATG2A | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.417); catalogued as rs1390703613; called by muse, mutect2, varscan2
- ATG2B | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs1217459951; called by muse, mutect2, varscan2
- ATG2B | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV63423040; called by muse, mutect2, varscan2
- ATG4A | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV58964120; called by muse, mutect2, varscan2
- ATG5 | c.698A>G p.E233G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs898608321, COSV58347762; called by muse, mutect2, varscan2
- ATM | c.1834C>A p.L612I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs747242300, COSV53764037; called by muse, mutect2, varscan2
- ATMIN | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs199541307, COSV55145212; called by muse, mutect2, varscan2
- ATMIN | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs751633732; called by muse, mutect2, varscan2
- ATP10B | c.3459C>A p.F1153L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV100515316; called by muse, mutect2
- ATP10B | c.2000C>A p.S667Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV59148108; called by muse, mutect2, varscan2
- ATP10D | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.851); catalogued as COSV56711753; called by muse, mutect2, varscan2
- ATP11B | c.1977G>T p.E659D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV60026635; called by muse, mutect2, varscan2
- ATP11C | c.3123C>A p.F1041L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59574829; called by muse, mutect2, varscan2
- ATP11C | c.1018-1G>A p.X340_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV59574953; called by mutect2, varscan2
- ATP11C | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as rs139162586; called by muse, mutect2, varscan2
- ATP12A | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs750121465, COSV54512200; called by muse, mutect2, varscan2
- ATP13A2 | c.3088G>A p.V1030M | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1215756025; called by muse, mutect2, varscan2
- ATP13A3 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.063); catalogued as rs753872961, COSV55463686; called by muse, mutect2, varscan2
- ATP13A4 | c.2563-2A>G p.X855_splice | Splice Site (SNP) | VAF 16/41 reads (39%) | catalogued as COSV61316004; called by muse, mutect2, varscan2
- ATP13A4 | c.2025G>A p.T675= | Splice Region (SNP) | VAF 8/66 reads (12%) | catalogued as rs200015919; called by mutect2, varscan2
- ATP1A2 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1274611333, COSV63404080; called by muse, mutect2, varscan2
- ATP1B4 | c.63C>T p.L21= | Splice Region (SNP) | VAF 11/48 reads (23%) | catalogued as rs377759056; called by muse, mutect2, varscan2
- ATP23 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs745657952, COSV55685897, COSV55686396; called by muse, mutect2, varscan2
- ATP23 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760875092; called by muse, mutect2, varscan2
- ATP23 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV55685539; called by muse, mutect2, varscan2
- ATP2A2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV58048028; called by muse, mutect2, varscan2
- ATP2B1 | c.3355C>T p.R1119* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV53806099; called by muse, mutect2, varscan2
- ATP2B4 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs200430665, COSV100397153; called by mutect2, varscan2
- ATP2C2 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs758964577; called by muse, varscan2
- ATP6V0A1 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as rs185595561; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs199698721, COSV57749267; called by mutect2, varscan2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by mutect2, varscan2
- ATP6V0A4 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.921); catalogued as rs778642531, COSV59472760, COSV59481332; called by muse, mutect2, varscan2
- ATP6V0D2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs201622171; called by mutect2, varscan2
- ATP6V1C1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV67777757; called by muse, mutect2, varscan2
- ATP6V1D | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.382); catalogued as rs781650138; called by muse, mutect2, varscan2
- ATP6V1E2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs549725173; called by muse, mutect2, varscan2
- ATP6V1H | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100778723; called by muse, mutect2, varscan2
- ATP7A | c.3623G>T p.R1208I | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs146392305, COSV100430491; called by muse, mutect2, varscan2
- ATP7B | c.2136G>A p.W712* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as rs1462815352, CM139958, COSV54445184; called by muse, mutect2, varscan2
- ATP8A1 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs749733890, COSV52533691; called by mutect2, varscan2
- ATP8B2 | c.385G>T p.D129Y (on ENST00000672630; = p.D96Y on NM_001005855.2) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59247255; called by muse, mutect2, varscan2
- ATP8B4 | c.1282A>G p.T428A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV52725699; called by muse, mutect2
- ATP9A | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs1164510008, COSV58764834; called by muse, mutect2, varscan2
- ATP9A | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs1161132652, COSV100124742; called by muse, varscan2
- ATR | c.6497A>G p.K2166R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs1337844230; called by muse, mutect2, varscan2
- ATR | c.3548G>A p.R1183Q | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as rs780802796, COSV63385620; called by muse, mutect2, varscan2
- ATR | c.1449G>T p.K483N | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs200968047; called by mutect2, varscan2
- ATRNL1 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.994); catalogued as rs1554924686, COSV58114600; called by muse, mutect2
- ATRX | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs782228142, COSV64883023; called by muse, mutect2, varscan2
- ATXN2 | c.1219G>T p.E407* (on ENST00000550104; = p.E247* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV101112846; called by muse, mutect2, varscan2
- ATXN3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | catalogued as COSV61494145; called by muse, mutect2, varscan2
- ATXN3L | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.001); catalogued as rs1279979260, COSV66075300; called by muse, mutect2, varscan2
- AVPR1B | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs782224020; called by muse, mutect2, varscan2
- AVPR1B | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV65638595; called by muse, mutect2, varscan2
- AXDND1 | c.2647C>T p.R883* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs761897633, COSV62640876, COSV62646075; called by muse, mutect2, varscan2
- AXDND1 | c.2755C>A p.L919I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100858461; called by muse, mutect2, varscan2
- AXIN1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV51984069; called by muse, mutect2, varscan2
- AXL | c.2398C>T p.R800W (on ENST00000301178 / NM_021913.5; = p.R791W on NM_001699.6) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1036430672, COSV56563418, COSV56565829; called by muse, mutect2, varscan2
- AZIN2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs151049367, COSV53860064; called by muse, mutect2, varscan2
- B3GALT1 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV59910212; called by muse, mutect2
- B3GALT4 | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV65851333; called by muse, mutect2, varscan2
- B3GAT2 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100017095; called by muse, mutect2, varscan2
- B3GNT5 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as rs763587705; called by mutect2, varscan2
- B3GNTL1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1460218860; called by muse, mutect2, varscan2
- B4GALNT2 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100302393; called by muse, mutect2, varscan2
- BAAT | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs765307307, COSV52290986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACE1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as rs747145464; called by muse, mutect2, varscan2
- BAHCC1 | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1347499123; called by muse, mutect2, varscan2
- BAHD1 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs774459113, COSV69084290; called by mutect2, varscan2
- BAK1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.435); catalogued as rs1372313307, COSV62349415; called by muse, mutect2, varscan2
- BAZ1B | c.1749A>C p.Q583H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV100289713; called by muse, mutect2, varscan2
- BBOF1 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as rs759037838; called by mutect2, varscan2
- BBS2 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs759714501, COSV55327535; called by muse, mutect2, varscan2
- BBS4 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs758013691; called by muse, mutect2, varscan2
- BBS9 | c.1864G>T p.E622* (on ENST00000242067 / NM_001348036.1; = p.E582* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV99629829; called by muse, mutect2, varscan2
- BCAT1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1241125592, COSV99678210; called by muse, mutect2, varscan2
- BCDIN3D | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs372331337; called by mutect2, varscan2
- BCHE | c.1021A>T p.K341* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs772337347, COSV52256230, COSV52258679; called by mutect2, varscan2
- BCKDHB | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV57518948; called by muse, mutect2, varscan2
- BCL11A | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1362432129, COSV59627949, COSV59634560; called by muse, mutect2, varscan2
- BCL11B | c.2653G>A p.D885N (on ENST00000357195 / NM_001282237.2; = p.D814N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV61734563; called by muse, mutect2, varscan2
- BCL2L1 | c.625C>T p.R209C (on ENST00000307677 / NM_001317919.2; = p.R146C on NM_001191.4) | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs759194807, COSV56966467; called by muse, mutect2, varscan2
- BCL2L11 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs778682749, COSV58027966; called by muse, mutect2, varscan2
- BCL2L14 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs777336275; called by muse, mutect2, varscan2
- BCL6B | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770283128, COSV53427614; called by muse, mutect2, varscan2
- BCLAF1 | c.2111G>T p.R704I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50358406; called by muse, mutect2, varscan2
- BCLAF1 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs528092692, COSV99219235; called by muse, mutect2, varscan2
- BDKRB2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs766530842, COSV60014789; called by mutect2, varscan2
- BDKRB2 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148172749; called by muse, mutect2, varscan2
- BDP1 | c.1289G>T p.R430I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62435106; called by muse, mutect2, varscan2
- BDP1 | c.3685G>T p.E1229* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV62432206; called by muse, mutect2, varscan2
- BDP1 | c.5950G>A p.E1984K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370425263; called by muse, mutect2, varscan2
- BEND2 | c.2179C>A p.L727I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV101192066; called by muse, mutect2, varscan2
- BEND5 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs201098567; called by muse, mutect2, varscan2
- BEND6 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.321); catalogued as rs79968708; called by muse, mutect2, varscan2
- BEND7 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100346852; called by muse, mutect2, varscan2
- BEX5 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.643); catalogued as rs781843692, COSV61328710; called by muse, mutect2, varscan2
- BFSP1 | c.535-1G>T p.X179_splice | Splice Site (SNP) | VAF 13/35 reads (37%) | catalogued as COSV64899915; called by muse, mutect2, varscan2
- BGN | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1418964197, COSV59036177; called by muse, mutect2, varscan2
- BHMT | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as rs369084085; called by muse, varscan2
- BICC1 | c.257C>T p.T86M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65862331; called by muse, mutect2, varscan2
- BICC1 | c.2216C>A p.T739N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1274392196, COSV99570829; called by muse, mutect2, varscan2
- BICD1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201842580; called by muse, mutect2, varscan2
- BICD1 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs200603103, COSV55678957; called by muse, mutect2, varscan2
- BICD2 | c.2469+1G>A p.X823_splice | Splice Site (SNP) | VAF 26/146 reads (18%) | catalogued as rs774445661; called by muse, mutect2, varscan2
- BICD2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs776152202, COSV63548515; called by muse, varscan2
- BICD2 | c.1715G>A p.R572H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs777902159, COSV63548831; called by muse, mutect2, varscan2
- BICDL1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765235056; called by muse, mutect2, varscan2
- BIRC6 | c.8659G>A p.V2887M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs755972507; called by muse, mutect2, varscan2
- BIRC6 | c.9392A>C p.K3131T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs765094572; called by muse, mutect2, varscan2
- BIRC7 | c.757A>G p.K253E (on ENST00000217169 / NM_139317.3; = p.K235E on NM_022161.4) | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1395487974; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57278938; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3198G>T p.E1066D | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV63244296; called by muse, mutect2, varscan2
- BLMH | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs767235807; called by muse, mutect2, varscan2
- BLNK | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782566012, COSV56414279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLVRA | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs387906596, CM112102, COSV55512431; called by mutect2, varscan2
- BLZF1 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.445); catalogued as COSV104412331; called by muse, mutect2, varscan2
- BMI1 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.421); catalogued as COSV64959350; called by muse, mutect2, varscan2
- BMI1 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV64958895; called by muse, mutect2, varscan2
- BMI1 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV64958851; called by muse, mutect2, varscan2
- BMP10 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV54895014; called by muse, mutect2, varscan2
- BMP15 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as rs781806618, COSV53141164; called by muse, varscan2
- BMP15 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as CM119145; called by muse, varscan2
- BMP4 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1225275541, COSV55415115; called by muse, mutect2
- BMP5 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV63706517; called by muse, mutect2, varscan2
- BMP7 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV67779434; called by muse, varscan2
- BMP7 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as rs767991677, COSV101216309; called by muse, varscan2
- BMP8B | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1309615617; called by mutect2, varscan2
- BMPR2 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs139591065; called by muse, mutect2, varscan2
- BMS1 | c.2662A>G p.I888V | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as rs2419108, COSV65733001; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BNC1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766072426, COSV61757106, COSV61758012; called by muse, varscan2
- BNIP3 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as rs376910597; called by muse, mutect2, varscan2
- BNIP5 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV101465134; called by muse, mutect2, varscan2
- BOC | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as rs373840149, COSV99847790; called by muse, mutect2, varscan2
- BOP1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1017931750; called by muse, mutect2, varscan2
- BPIFA3 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs754777967, COSV100967018; called by mutect2, varscan2
- BPIFB4 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs747659473, COSV64951804; called by mutect2, varscan2
- BPNT2 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs747764009, COSV52906615; called by mutect2, varscan2
- BRAF | c.1960T>C p.S654P (on ENST00000288602 / NM_001374244.1; = p.S614P on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV56062937; called by muse, varscan2
- BRAF | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs397516884, COSV56374840; called by muse, mutect2, varscan2
- BRCA1 | c.3608G>A p.R1203Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs55930959, CM042676, COSV58794111; ClinVar: conflicting interpretations of pathogenicity / likely benign / benign; called by muse, mutect2, varscan2
- BRCA2 | c.955A>C p.N319H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV66451048; called by muse, mutect2, varscan2
- BRCA2 | c.4531G>A p.E1511K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs376338226, COSV66458357; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- BRCA2 | c.9819C>A p.F3273L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV101200891; called by muse, mutect2, varscan2
- BRCC3 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.005); catalogued as rs782698211, COSV57462065; called by muse, mutect2, varscan2
- BRD1 | c.3037G>A p.E1013K (on ENST00000216267 / NM_001349940.1; = p.E1144K on NM_001304808.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1046139158, COSV53462584; called by muse, mutect2, varscan2
- BRD1 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53457027; called by muse, mutect2, varscan2
- BRD4 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1453756538, COSV54584038; called by muse, mutect2, varscan2
- BRDT | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV100746272, COSV62864172, COSV62864212; called by muse, mutect2, varscan2
- BRICD5 | c.724G>A p.D242N (on ENST00000562360; = p.D210N on NM_182563.3) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142825627; called by mutect2, varscan2
- BRINP1 | c.2058C>A p.F686L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.075); catalogued as COSV99774738; called by muse, mutect2, varscan2
- BRINP2 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV64175147; called by muse, mutect2, varscan2
- BRINP3 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs146936488; called by muse, mutect2, varscan2
- BRIP1 | c.2582C>T p.S861F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51998447; called by mutect2, varscan2
- BRIX1 | c.211A>C p.N71H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs752419046, COSV57715348; called by muse, mutect2, varscan2
- BRWD1 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); catalogued as rs752034028, COSV60892948; called by muse, mutect2, varscan2
- BRWD3 | c.4982G>T p.G1661V | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.2); catalogued as COSV64748225, COSV64751991; called by muse, mutect2, varscan2
- BRWD3 | c.2618G>T p.R873I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV64751110, COSV64753112; called by muse, mutect2, varscan2
- BRWD3 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as rs777031555, COSV64748881; called by muse, mutect2, varscan2
- BSN | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs753633315, COSV56514137; called by muse, mutect2, varscan2
- BSN | c.5280C>A p.D1760E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV56515119; called by muse, mutect2
- BSX | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV100545259; called by muse, mutect2, varscan2
- BTAF1 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs1412442556; called by muse, mutect2, varscan2
- BTBD16 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as rs751310118; called by muse, mutect2, varscan2
- BTD | c.-14T>G | Splice Region (SNP) | VAF 10/61 reads (16%) | catalogued as COSV57729831; called by muse, mutect2, varscan2
- BTD | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.107); catalogued as rs1020171739; called by muse, mutect2, varscan2
- BTD | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs185225945, COSV100329929; called by mutect2, varscan2
- BTG3 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1217099989, COSV60286049; called by muse, mutect2, varscan2
- BTN2A2 | c.1359A>C p.E453D | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as rs777320173; called by muse, mutect2, varscan2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, mutect2, varscan2
- BUD13 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52768537, COSV52770269; called by muse, mutect2, varscan2
- BUD23 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147638131; called by muse, varscan2
- BUD31 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV56117328; called by mutect2, varscan2
- BZW2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs146833365, COSV99334294; called by mutect2, varscan2
- C10orf90 | c.1735C>T p.R579C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs777823961, COSV52959414; called by mutect2, varscan2
- C10orf90 | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1357933121, COSV52962888; called by muse, mutect2, varscan2
- C11orf58 | c.123C>A p.F41L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV57178358; called by muse, mutect2, varscan2
- C11orf65 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104431218; called by muse, varscan2
- C11orf65 | c.489C>A p.F163L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV67597555; called by muse, varscan2
- C11orf80 | c.898C>A p.L300I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60928737; called by mutect2, varscan2
- C11orf87 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59358617; called by muse, mutect2, varscan2
- C12orf40 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100210573; called by muse, mutect2, varscan2
- C12orf50 | c.1075T>C p.S359P | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53894889; called by muse, mutect2
- C12orf50 | c.869G>T p.R290I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53898675; called by muse, mutect2, varscan2
- C14orf28 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as rs1202601891, COSV100290224; called by muse, mutect2, varscan2
- C14orf39 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as COSV58779891; called by muse, mutect2, varscan2
- C16orf71 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.739); catalogued as rs866159304, COSV54794542; called by muse, mutect2, varscan2
- C1QTNF1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs767734960, COSV59262440; called by muse, mutect2, varscan2
- C1QTNF2 | c.826G>A p.D276N (on ENST00000393975; = p.D231N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764375956; called by mutect2, varscan2
- C1QTNF2 | c.311G>A p.R104Q (on ENST00000393975; = p.R59Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs759937511, COSV67432358; called by mutect2, varscan2
- C1QTNF9B | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747892890; called by mutect2, varscan2
- C1S | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.19); catalogued as rs148512159, COSV61071990; called by mutect2, varscan2
- C1orf100 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 14/29 reads (48%) | catalogued as COSV104411958; called by muse, mutect2, varscan2
- C1orf109 | c.478C>A p.L160I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs950726138; called by muse, mutect2
- C1orf141 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100924422; called by muse, mutect2, varscan2
- C1orf141 | c.757A>C p.I253L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100924425; called by muse, mutect2, varscan2
- C1orf226 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs746587084; called by muse, varscan2
- C1orf87 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100967271; called by muse, mutect2, varscan2
- C2CD2 | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs1048773893; called by muse, mutect2, varscan2
- C2CD3 | c.4969C>T p.R1657W | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1251259043; called by muse, mutect2
- C2CD3 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs769847567, COSV58091238; called by muse, mutect2, varscan2
- C2CD5 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753259599, COSV61723055; called by muse, varscan2
- C2orf80 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1439189051; called by muse, mutect2
- C3 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs753979097, COSV99836637; called by mutect2, varscan2
- C3AR1 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as rs868210869; called by muse, mutect2, varscan2
- C3orf20 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.086); catalogued as COSV53785704; called by muse, mutect2, varscan2
- C3orf20 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs765984059, COSV53783252; called by muse, varscan2
- C3orf70 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as rs778561628; called by muse, mutect2, varscan2
- C4A | c.3200C>T p.A1067V | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs747757875, COSV101418336; called by muse, mutect2
- C5 | c.1878C>A p.F626L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV56325849, COSV56330272; called by muse, mutect2, varscan2
- C6 | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV54705890, COSV99667070; called by muse, mutect2, varscan2
- C6orf118 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV57818555, COSV57819893; called by muse, mutect2, varscan2
- C6orf58 | c.194A>C p.K65T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1166642919; called by muse, mutect2, varscan2
- C8orf34 | c.1326C>T p.F442= | Splice Region (SNP) | VAF 7/28 reads (25%) | catalogued as rs201463505, COSV57396967; called by muse, mutect2, varscan2
- C9orf131 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs764495713; called by muse, mutect2, varscan2
- C9orf131 | c.2118G>A p.W706* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV56611612; called by muse, mutect2, varscan2
- C9orf72 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV66154636; called by muse, mutect2, varscan2
- CA14 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV64257780; called by muse, mutect2, varscan2
- CA8 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.102); catalogued as COSV100526726; called by muse, mutect2, varscan2
- CABP1 | c.706G>T p.E236* (on ENST00000316803 / NM_001033677.1; = p.E33* on NM_004276.5) | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV56459655; called by muse, mutect2, varscan2
- CABP1 | c.844G>T p.D282Y (on ENST00000316803 / NM_001033677.1; = p.D79Y on NM_004276.5) | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56460050; called by muse, mutect2, varscan2
- CABP4 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs779788706, COSV56887662; called by muse, mutect2, varscan2
- CABP5 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53152250; called by muse, varscan2
- CACNA1A | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM144895, COSV64204041; called by muse, mutect2, varscan2
- CACNA1C | c.2129C>T p.S710L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV59695046; called by muse, mutect2, varscan2
- CACNA1D | c.5204C>T p.S1735L (on ENST00000350061 / NM_001128840.3; = p.S1755L on NM_000720.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs1461261149, COSV55437928; called by mutect2, varscan2
- CACNA1D | c.6259G>A p.E2087K (on ENST00000350061 / NM_001128840.3; = p.E2107K on NM_000720.4) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs762059527, COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CACNA1E | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100703534, COSV62384227; called by muse, mutect2, varscan2
- CACNA1E | c.2243G>T p.R748I | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV100702102, COSV100705465; called by muse, mutect2, varscan2
- CACNA1E | c.2482C>T p.R828W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV62381010; called by muse, mutect2, varscan2
- CACNA1E | c.3545G>A p.R1182H | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs376174454; called by muse, mutect2, varscan2
- CACNA1E | c.4947C>A p.F1649L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV100701098, COSV100704864; called by muse, varscan2
- CACNA1F | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs782299485; called by muse, mutect2, varscan2
- CACNA1H | c.6676A>G p.T2226A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1224248651; called by muse, mutect2
- CACNA1I | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as rs934554704; called by muse, varscan2
- CACNA1I | c.3928G>A p.V1310M | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1236403585; called by muse, mutect2, varscan2
- CACNA1I | c.4618G>A p.A1540T | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100359276; called by muse, varscan2
- CACNA1S | c.3853G>A p.G1285S | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768535906, COSV62940596, COSV62941559; called by muse, mutect2, varscan2
- CACNA1S | c.3231G>T p.K1077N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763299733, COSV100754971, COSV62937030; called by mutect2, varscan2
- CACNA2D1 | c.2018C>T p.S673L (on ENST00000356253 / NM_001366867.1; = p.S661L on NM_000722.4) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs779137994, COSV62373938; called by muse, varscan2
- CACNA2D1 | c.1934C>T p.S645L (on ENST00000356253 / NM_001366867.1; = p.S633L on NM_000722.4) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.175); catalogued as rs149510838; called by muse, varscan2
- CACNB2 | c.436G>T p.D146Y (on ENST00000324631 / NM_201596.3; = p.D91Y on NM_000724.4) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs936451598, COSV56647146; called by muse, mutect2, varscan2
- CACNB2 | c.1880G>A p.R627H (on ENST00000324631 / NM_201596.3; = p.R572H on NM_000724.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.992); catalogued as rs758934103, COSV56627222; called by muse, mutect2, varscan2
- CACUL1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs746314775, COSV60993535; called by muse, mutect2, varscan2
- CADM2 | c.883C>T p.R295* (on ENST00000407528 / NM_001167674.2; = p.R297* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as rs781077819, COSV67361182; called by muse, mutect2, varscan2
- CADM3 | c.235C>T p.R79* (on ENST00000368125 / NM_001127173.3; = p.R113* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV63686065; called by muse, mutect2, varscan2
- CADPS | c.3170C>T p.A1057V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375576173; called by muse, mutect2, varscan2
- CADPS | c.1325+1G>T p.X442_splice | Splice Site (SNP) | VAF 29/86 reads (34%) | catalogued as rs749964509, COSV51871357; called by muse, mutect2, varscan2
- CALCOCO2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs765125675, COSV104386233, COSV51952812; called by muse, mutect2, varscan2
- CALCOCO2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV51951591; called by muse, mutect2
- CAMK1D | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV66608344; called by muse, mutect2, varscan2
- CAMKK2 | c.1407G>T p.E469D | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV61217564; called by muse, mutect2, varscan2
- CAMKK2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61214188; called by muse, mutect2, varscan2
- CAMLG | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765331970, COSV51804427; called by muse, mutect2, varscan2
- CAMSAP1 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as rs780360172, COSV56720449; called by muse, mutect2, varscan2
- CAMSAP1 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as rs571335059; called by muse, mutect2, varscan2
- CAMSAP1 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV56722294; called by muse, mutect2, varscan2
13,172 further variants in this file (10,073 protein-altering or splice-affecting, 2,773 silent, 326 other) are not listed here.
